FM case AD4290 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas.
https://portal.gdc.cancer.gov/cases/d982d2fd-c7c7-4162-b787-b1c85f4d4488

Male, 53.3 years: Adenocarcinoma, NOS (ICD-O-3 8140/3); specimen biopsied or resected from the abdomen. Tumor nuclei on the sequenced sample's slide: 60% (pathologist estimate recorded by GDC). Sample type: Tumor.
